Somatic mutation profile of tumor specimen TCGA-FS-A1Z7-06A (aliquot TCGA-FS-A1Z7-06A-11D-A197-08) from TCGA case TCGA-FS-A1Z7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 20.0 years (7,307 days).
Specimen TCGA-FS-A1Z7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d632e1b5-dda8-470b-818b-ced5bac0ac58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1Z7-10A (Blood Derived Normal), aliquot TCGA-FS-A1Z7-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/544fef3c-ca9f-4739-b6ea-655927a5cb99

The open-access MAF lists 221 somatic variants for this specimen: 139 protein-altering or splice-affecting, 75 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 75, Nonsense Mutation 6, Splice Region 3, Intron 3, RNA 2, Splice Site 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PLCE1 | c.5890C>T p.R1964* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as rs775052849, COSV53368895; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1117C>T p.P373S (on ENST00000272895 / NM_173076.3; = p.P55S on NM_015657.3) | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as rs1302929279, COSV55973119; called by muse, mutect2, varscan2
- ABI3BP | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs866268966, COSV52543037, COSV52549187; called by muse, mutect2, varscan2
- ACBD7 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs200704311, COSV62252241; called by muse, mutect2, varscan2
- ADGRE1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.045); catalogued as rs755844453, COSV51676264; called by muse, mutect2, varscan2
- ADGRF4 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV51956832; called by muse, mutect2, varscan2
- AGBL2 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV54095048; called by muse, mutect2, varscan2
- AGBL5 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747996062, COSV59938069; called by muse, mutect2, varscan2
- AK9 | c.3089T>G p.L1030R | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV58149064; called by muse, mutect2, varscan2
- AKAP13 | c.8116G>A p.E2706K (on ENST00000394518 / NM_007200.5; = p.E2710K on NM_006738.6) | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as COSV63458349, COSV63467936; called by muse, mutect2
- AL441992.2 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56916323; called by muse, mutect2, varscan2
- ARHGEF10L | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs554759887, COSV99393971; called by muse, mutect2, varscan2
- ATAD2 | c.3647G>A p.G1216E | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV54885834; called by muse, mutect2, varscan2
- BBX | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV57893276; called by muse, mutect2, varscan2
- C3orf22 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV59073243; called by muse, mutect2
- CACNA1B | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757636040, COSV53120239; called by muse, mutect2, varscan2
- CAPN5 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV53690829; called by muse, mutect2, varscan2
- CCNC | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58334848; called by muse, mutect2, varscan2
- CD79A | c.152A>C p.H51P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs781936282, COSV55739448; called by muse, varscan2
- CDH23 | c.8491G>A p.E2831K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV56485937; called by muse, mutect2, varscan2
- CELSR3 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.121); catalogued as COSV99373264; called by muse, mutect2, varscan2
- CELSR3 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99375216; called by muse, mutect2, varscan2
- CENPC | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56625951; called by muse, mutect2, varscan2
- CER1 | c.507+1G>A p.X169_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV101097937; called by muse, mutect2, varscan2
- CHRNA9 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 143/254 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59575011; called by muse, mutect2, varscan2
- CLEC6A | c.193A>C p.T65P | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65988072; called by muse, mutect2, varscan2
- CNGB3 | c.940T>C p.Y314H | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1343359545, COSV60697148; called by muse, mutect2, varscan2
- COL2A1 | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61533613; called by muse, mutect2, varscan2
- COL4A4 | c.3700C>T p.P1234S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.328); catalogued as rs757430966, COSV61632513; called by muse, mutect2, varscan2
- COL4A4 | c.3472G>A p.D1158N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV61629657, COSV61629917; called by muse, mutect2, varscan2
- COL6A6 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs767722528, COSV62035561; called by muse, mutect2, varscan2
- CTNNA2 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58155619; called by muse, mutect2, varscan2
- CYP2C18 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.121); catalogued as COSV53674683; called by muse, mutect2, varscan2
- CYP2S1 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59507160; called by muse, mutect2, varscan2
- CYP4A11 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 89/321 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV60225243; called by muse, mutect2, varscan2
- CYTH2 | c.994G>A p.G332R (on ENST00000427476; = p.G331R on NM_004228.7) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs765967604, COSV57310581; called by muse, mutect2, varscan2
- DGKD | c.2602G>A p.D868N (on ENST00000264057 / NM_152879.3; = p.D824N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs764501943, COSV51095701; called by muse, mutect2, varscan2
- DHX9 | c.1423T>C p.F475L | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62361821; called by muse, mutect2, varscan2
- DNAH5 | c.6235C>T p.L2079F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs371463953; called by muse, mutect2, varscan2
- DOCK3 | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56546023; called by muse, mutect2, varscan2
- EHMT2 | c.2615C>T p.S872L | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV64997810; called by muse, mutect2, varscan2
- ELF5 | c.610C>T p.R204W (on ENST00000312319 / NM_198381.2; = p.R194W on NM_001422.4) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759245139, COSV56629071; called by muse, mutect2, varscan2
- EPB42 | c.1448G>A p.S483N (on ENST00000441366 / NM_001114134.2; = p.S513N on NM_000119.3) | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV55751343; called by muse, mutect2, varscan2
- EPS8L3 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV62610432; called by muse, mutect2, varscan2
- ERICH3 | c.3425G>A p.G1142E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs754644777, COSV58616404; called by muse, mutect2, varscan2
- EVPL | c.5173G>A p.E1725K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56915109; called by muse, mutect2, varscan2
- EXOC7 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as rs867741124, COSV58741365; called by muse, mutect2, varscan2
- FAM71B | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV57230562; called by muse, varscan2
- FOXP1 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV59526847; called by muse, mutect2, varscan2
- FPR1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as rs866791532, COSV59053371; called by muse, mutect2, varscan2
- FRAS1 | c.6276G>A p.G2092= | Splice Region (SNP) | VAF 25/49 reads (51%) | catalogued as COSV53641843; called by muse, mutect2, varscan2
- FREM1 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs996489061, COSV66528997; called by muse, mutect2, varscan2
- FSIP1 | c.1321T>A p.F441I | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV63226609; called by muse, mutect2, varscan2
- GADL1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV56984714; called by muse, mutect2, varscan2
- GBP7 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54011555; called by muse, varscan2
- GRIK1 | c.2608-1G>A p.X870_splice | Splice Site (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100518107; called by muse, mutect2
- HAVCR1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761993425, COSV59403238; called by muse, mutect2, varscan2
- HCN1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100301533, COSV57533867; called by muse, mutect2, varscan2
- HSPB8 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs768405176, COSV56139153, COSV99931441, COSV99931504; called by muse, mutect2, varscan2
- HTR2C | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV52222439; called by muse, mutect2, varscan2
- HTT | c.6170C>T p.S2057F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100751334; called by muse, mutect2, varscan2
- IFT122 | c.3127C>T p.R1043C (on ENST00000348417 / NM_052989.3; = p.R984C on NM_018262.4) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs555281580; called by muse, mutect2, varscan2
- IL1B | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV54522852, COSV54523054; called by muse, mutect2, varscan2
- ILDR1 | c.1319G>A p.R440K (on ENST00000344209 / NM_001199799.2; = p.R396K on NM_175924.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV56553311; called by muse, mutect2, varscan2
- IQGAP3 | c.2608G>C p.A870P | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV63254187; called by muse, mutect2, varscan2
- IRF2 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 27/51 reads (53%) | catalogued as COSV66928371; called by muse, mutect2, varscan2
- KMT2D | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1334315280, COSV56480075; called by muse, mutect2, varscan2
- LCT | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51547403; called by muse, mutect2, varscan2
- LRP1B | c.6419G>A p.R2140K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV67266627; called by muse, mutect2, varscan2
- MAGEC3 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); catalogued as COSV68924221; called by muse, mutect2, varscan2
- MAST2 | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1194282496, COSV63621118; called by muse, mutect2, varscan2
- MBD5 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as rs753137611, COSV68696761; called by muse, mutect2, varscan2
- MDM1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV57448632; called by muse, mutect2, varscan2
- MED12L | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); catalogued as rs376593902; called by muse, mutect2, varscan2
- MUC16 | c.9403G>A p.A3135T | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV67471615; called by muse, mutect2, varscan2
- MUC16 | c.3683C>T p.S1228L | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs778561167, COSV67465815; called by muse, mutect2, varscan2
- MUC16 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV67452487, COSV67467117; called by muse, mutect2
- MUC2 | c.3955G>A p.D1319N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs777587897; called by mutect2, varscan2
- MUC4 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.934); catalogued as COSV62168114, COSV62188988; called by muse, mutect2, varscan2
- MYOM2 | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771411219, COSV50758155; called by muse, mutect2, varscan2
- NLGN1 | c.2224C>T p.H742Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.596); catalogued as COSV100850373, COSV64339098; called by muse, mutect2, varscan2
- NPAS4 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV60652551; called by muse, mutect2, varscan2
- OR6K2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as rs1399117017, COSV62743332; called by muse, mutect2, varscan2
- OTUD6A | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57973736; called by muse, mutect2, varscan2
- OTUD6A | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772576162, COSV100611098; called by muse, varscan2
- PCDHA7 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.752); catalogued as rs782422719, COSV65345501; called by muse, varscan2
- PCDHB5 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs61747444, COSV50658685; called by muse, mutect2, varscan2
- PEG3 | c.4309G>A p.G1437R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55645200; called by muse, mutect2, varscan2
- PREX2 | c.2329G>A p.G777R | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs535902535, COSV55796069; called by muse, mutect2, varscan2
- PRPF8 | c.4756C>T p.H1586Y | Missense Mutation (SNP) | VAF 123/407 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59267184; called by muse, mutect2, varscan2
- PRUNE2 | c.4350G>A p.M1450I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV65046747; called by muse, mutect2, varscan2
- PTPRT | c.3538C>T p.Q1180* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as COSV61969777, COSV62000873, COSV62028893; called by muse, mutect2, varscan2
- PZP | c.2129G>A p.R710K | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.82); PolyPhen benign (0.017); catalogued as COSV54357437; called by muse, mutect2, varscan2
- RMI1 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57936591; called by muse, mutect2, varscan2
- RNASE9 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV100141296, COSV58881080; called by muse, mutect2, varscan2
- ROCK2 | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV59963873; called by muse, mutect2, varscan2
- RUSC2 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1477910773, COSV63430190; called by muse, mutect2, varscan2
- RYR3 | c.7093G>A p.V2365M (on ENST00000389232; = p.V2366M on NM_001036.6) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66806158; called by muse, mutect2, varscan2
- RYR3 | c.8071G>A p.G2691R (on ENST00000389232; = p.G2692R on NM_001036.6) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.851); catalogued as rs1358919213, COSV66806160; called by muse, mutect2, varscan2
- SEMG1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.973); catalogued as COSV54874059; called by muse, mutect2, varscan2
- SGSH | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58340385; called by muse, mutect2, varscan2
- SLAMF8 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763262299, COSV56989707; called by muse, mutect2, varscan2
- SLC26A4 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55918819; called by muse, mutect2, varscan2
- SLC35A5 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV53727908; called by muse, mutect2, varscan2
- SLC6A20 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs767820251, COSV62073233; called by muse, mutect2, varscan2
- SLCO1B1 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57015999; called by muse, mutect2, varscan2
- SORL1 | c.4217C>T p.S1406L | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52759799; called by muse, mutect2, varscan2
- SPAG16 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV59103890; called by muse, mutect2, varscan2
- STAG1 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52621995; called by muse, mutect2
- SVEP1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV57045853; called by muse, mutect2, varscan2
- SYNPO2 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61115952; called by muse, mutect2, varscan2
- SYTL3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs183416046, COSV51914650; called by muse, mutect2, varscan2
- TAS1R1 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59840630; called by muse, mutect2, varscan2
- TDRD5 | c.2700G>A p.V900= | Splice Region (SNP) | VAF 23/98 reads (23%) | catalogued as rs760102745, COSV54240515; called by muse, mutect2, varscan2
- TFAP2C | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52372939; called by muse, mutect2, varscan2
- THSD7B | c.1913A>C p.E638A | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV55730660; called by muse, mutect2
- TJAP1 | c.1424C>T p.P475L (on ENST00000372445 / NM_001146016.1; = p.P465L on NM_080604.3) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52501148, COSV52503439; called by muse, mutect2, varscan2
- TMCO5A | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV60465793; called by muse, mutect2, varscan2
- TMEM199 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as COSV50228859; called by muse, mutect2, varscan2
- TMPRSS11E | c.261G>A p.V87= | Splice Region (SNP) | VAF 74/127 reads (58%) | catalogued as COSV59520879; called by muse, mutect2, varscan2
- TP63 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs558374141, COSV53218998; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRAM2 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as rs750849216, COSV51734524, COSV99480202; called by muse, mutect2, varscan2
- TRPC3 | c.2263G>A p.D755N (on ENST00000379645 / NM_001366479.2; = p.D682N on NM_003305.2) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV53380372; called by muse, mutect2, varscan2
- TTN | c.66341G>A p.G22114D (on ENST00000591111; = p.G14690D on NM_003319.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | PolyPhen probably damaging (1); catalogued as COSV100633033; called by muse, mutect2, varscan2
- TTN | c.66340G>A p.G22114S (on ENST00000591111; = p.G14690S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | PolyPhen probably damaging (0.999); catalogued as COSV100633035; called by muse, mutect2, varscan2
- TTN | c.18607G>A p.E6203K (on ENST00000591111; = p.E5276K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | PolyPhen benign (0.017); catalogued as COSV59914803, COSV60176535; called by muse, mutect2, varscan2
- TTN | c.9812C>T p.S3271F (on ENST00000591111; = p.S3225F on NM_003319.4) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | PolyPhen benign (0.001); catalogued as rs867536098, COSV59891245, COSV60211933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT1A9 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs777189828, COSV60850020; called by muse, mutect2, varscan2
- UNC5D | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs199800648, COSV54775407, COSV54829586; called by muse, mutect2, varscan2
- VPS33A | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs150472752, COSV57356020, COSV99931365; called by muse, mutect2, varscan2
- WNT7A | c.989G>A p.W330* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV53201677; called by muse, mutect2, varscan2
- ZNF354A | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 39/143 reads (27%) | catalogued as rs1357962381, COSV59984706; called by muse, mutect2, varscan2
- ZNF786 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 75/415 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1348669702, COSV60277532; called by muse, mutect2, varscan2
- ZNF804A | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV56449169; called by muse, mutect2, varscan2
- ZNF804A | c.2453G>A p.R818K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV100168943, COSV56467993; called by muse, mutect2, varscan2
- ZSCAN1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.084); catalogued as COSV56607873; called by muse, mutect2, varscan2
- ANXA8L1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRCIN1 | c.2992C>T p.H998Y (on ENST00000621492; = p.H964Y on NM_025248.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ABCC4 | c.1671C>T p.L557= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV65311215; called by muse, mutect2, varscan2
- ADAMTSL3 | c.156G>A p.G52= | Silent (SNP) | VAF 108/228 reads (47%) | catalogued as COSV54445112; called by muse, mutect2, varscan2
- ANK3 | c.12132T>G p.G4044= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV55078218; called by muse, mutect2, varscan2
- ANKRD11 | c.5502C>T p.P1834= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV56370135; called by muse, mutect2, varscan2
- ANKRD30A | c.3195G>A p.V1065= (on ENST00000611781; = p.V1009= on NM_052997.2) | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs868226067, COSV64619218; called by muse, mutect2, varscan2
- AP002512.3 | c.1242G>A p.R414= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV54406196; called by muse, mutect2, varscan2
- ARHGAP33 | c.2382C>T p.S794= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs756531666, COSV50154454; called by muse, mutect2, varscan2
- ASPH | c.1242C>T p.V414= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV65246404; called by muse, mutect2, varscan2
- ATPAF2 | c.819C>T p.I273= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV58265920; called by muse, mutect2, varscan2
- CCDC87 | c.2496C>T p.A832= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as rs1305386461, COSV59580383; called by muse, mutect2, varscan2
- CDH13 | c.1164G>A p.K388= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs1341134466, COSV51862204; called by muse, mutect2, varscan2
- CDH7 | c.132G>A p.R44= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV59893248; called by muse, mutect2, varscan2
- CDHR2 | c.372C>T p.F124= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV56144228; called by muse, mutect2, varscan2
- CDK10 | c.918C>T p.Y306= (on ENST00000353379 / NM_052988.5; = p.Y235= on NM_052987.4) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs932133225, COSV57048557; called by muse, mutect2, varscan2
- CEMIP2 | c.4104C>T p.V1368= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV65489204; called by muse, mutect2, varscan2
- CEP131 | c.2505C>T p.A835= (on ENST00000269392 / NM_001319228.2; = p.A832= on NM_014984.4) | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV53955951; called by muse, mutect2, varscan2
- CHD4 | c.4440T>C p.L1480= (on ENST00000357008 / NM_001363606.2; = p.L1493= on NM_001273.5) | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as COSV58909407; called by muse, mutect2, varscan2
- CHRM2 | c.834G>A p.E278= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV57766502, COSV57782901; called by muse, mutect2, varscan2
- CNTNAP2 | c.1197C>T p.F399= | Silent (SNP) | VAF 66/116 reads (57%) | catalogued as rs754297905, COSV62223172; called by muse, mutect2, varscan2
- CRYBA2 | c.15C>T p.P5= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV55387722; called by muse, mutect2, varscan2
- CRYBG2 | c.1056C>T p.P352= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs745762898, COSV57489403; called by muse, mutect2, varscan2
- CSMD1 | c.9726C>T p.F3242= (on ENST00000520002; = p.F3241= on NM_033225.6) | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV59374413; called by muse, mutect2, varscan2
- CYP2C9 | c.1353C>T p.S451= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV53252132; called by muse, mutect2, varscan2
- DMAC2 | c.546C>T p.A182= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs781789468, COSV55729526; called by muse, mutect2, varscan2
- DUSP4 | c.1092C>T p.F364= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs368211989; called by muse, mutect2, varscan2
- EHMT1 | c.3456C>T p.V1152= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV101509713, COSV71778499; called by muse, mutect2, varscan2
- ENOX1 | c.96G>A p.A32= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs139717285, COSV54887798; called by muse, mutect2, varscan2
- GJB2 | c.420C>T p.I140= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV67010874; called by muse, mutect2, varscan2
- GRIA1 | c.1485C>T p.I495= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV53621108; called by muse, varscan2
- GRIN2B | c.783G>A p.L261= | Silent (SNP) | VAF 47/66 reads (71%) | catalogued as rs944359941, COSV74207495; called by muse, mutect2, varscan2
- GTF3C5 | c.1305G>A p.R435= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV59601733; called by muse, mutect2, varscan2
- HTT | c.6171C>T p.S2057= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100751171; called by muse, mutect2
- ICAM1 | c.453C>T p.L151= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53426835; called by muse, mutect2, varscan2
- IFT122 | c.3126C>T p.I1042= (on ENST00000348417 / NM_052989.3; = p.I983= on NM_018262.4) | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV56205041; called by muse, mutect2, varscan2
- IQSEC1 | c.69C>T p.V23= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs368596525; called by muse, mutect2, varscan2
- ITGB4 | c.5145G>A p.K1715= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs908030359, COSV52331778; called by muse, varscan2
- KCNN1 | c.990C>T p.S330= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV55841759; called by muse, mutect2
- LAMB2 | c.3471C>T p.R1157= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV59737490; called by muse, mutect2, varscan2
- LCT | c.5736G>A p.G1912= | Silent (SNP) | VAF 82/256 reads (32%) | catalogued as COSV51556461; called by muse, mutect2, varscan2
- LMNA | c.984C>T p.A328= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1263926028, COSV61543908; called by muse, mutect2, varscan2
- LRRC27 | c.777C>T p.I259= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV59811447; called by muse, mutect2, varscan2
- LRRC66 | c.1476G>A p.G492= | Silent (SNP) | VAF 55/98 reads (56%) | catalogued as COSV58636476; called by muse, mutect2, varscan2
- MAD1L1 | c.805C>T p.L269= | Silent (SNP) | VAF 74/124 reads (60%) | catalogued as rs767637745, COSV56245836; called by muse, mutect2, varscan2
- MAP10 | c.2283G>A p.V761= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as COSV69364713; called by muse, mutect2, varscan2
- MLH1 | c.31C>T p.L11= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs864622596, HD060522, COSV51623314, COSV51623694; ClinVar: likely benign; called by muse, mutect2, varscan2
- MMP10 | c.1155G>A p.R385= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as rs537908479, COSV54247544; called by muse, mutect2, varscan2
- MST1 | c.414G>C p.T138= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1007967360, COSV56536461; called by muse, mutect2, varscan2
- MUC3A | c.9006C>T p.T3002= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV60223768; called by muse, mutect2
- MYBBP1A | c.249C>T p.V83= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs912812170, COSV54603313; called by muse, mutect2, varscan2
- MYH4 | c.4854C>T p.I1618= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV55124871; called by muse, mutect2, varscan2
- NLE1 | c.300C>A p.V100= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs764015442, COSV62605060; called by muse, mutect2, varscan2
- OR10AG1 | c.607C>T p.L203= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV56634436, COSV56634554, COSV99044229; called by muse, mutect2, varscan2
- OR10H4 | c.885G>A p.R295= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as rs772539660, COSV59061247; called by muse, mutect2, varscan2
- OR2T35 | c.879G>A p.R293= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- PAK5 | c.564G>A p.L188= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as COSV62036350; called by muse, mutect2, varscan2
- PLXNB2 | c.2949C>T p.P983= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs746421581, COSV63784088; called by muse, mutect2, varscan2
- POLD1 | c.2040C>T p.P680= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV70957022; called by muse, mutect2, varscan2
- PRDM1 | c.1527C>T p.A509= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1336674158, COSV64846788; called by muse, mutect2, varscan2
- REM1 | c.72C>T p.S24= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV52429750; called by muse, mutect2, varscan2
- SCN4A | c.144G>A p.E48= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV71128809; called by muse, mutect2, varscan2
- SCN9A | c.2751C>T p.F917= (on ENST00000303354; = p.F906= on NM_002977.3) | Silent (SNP) | VAF 76/232 reads (33%) | catalogued as COSV57621954; called by muse, varscan2
- SEMA6C | c.126C>T p.S42= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1283816649, COSV59007128; called by muse, mutect2
- SLC1A7 | c.984C>T p.I328= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1284687332, COSV65201128; called by muse, mutect2, varscan2
- SLC5A10 | c.1548C>T p.F516= (on ENST00000395645 / NM_001042450.4; = p.F532= on NM_152351.5) | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs764747837, COSV52414407; called by muse, mutect2
- SLC6A20 | c.453G>A p.R151= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV62070235; called by muse, mutect2, varscan2
- SORL1 | c.5787G>A p.P1929= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs746158920, COSV52761397; called by muse, mutect2, varscan2
- SRPX2 | c.300G>A p.R100= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV65934437; called by muse, mutect2, varscan2
- TBC1D2 | c.1428C>T p.H476= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV59788266; called by muse, mutect2, varscan2
- TIE1 | c.1887C>T p.G629= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100992066, COSV65251138; called by muse, mutect2, varscan2
- TMEFF2 | c.204C>T p.L68= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV55839348; called by muse, mutect2, varscan2
- TMPRSS2 | c.825C>T p.V275= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV59826905; called by muse, mutect2, varscan2
- TRPC3 | c.1284C>T p.V428= (on ENST00000379645 / NM_001366479.2; = p.V355= on NM_003305.2) | Silent (SNP) | VAF 31/44 reads (70%) | catalogued as rs765059359, COSV53376823; called by muse, mutect2, varscan2
- TUBA3C | c.702C>T p.I234= | Silent (SNP) | VAF 101/213 reads (47%) | catalogued as rs142245280; called by muse, mutect2, varscan2
- VPS37B | c.696C>T p.A232= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs373595408; called by muse, mutect2, varscan2
- ZNF451 | c.1272T>C p.F424= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV62599708; called by muse, mutect2, varscan2
- ARMC5 | c.1864+212C>T | Intron (SNP) | VAF 17/53 reads (32%) | catalogued as COSV51656087; called by muse, mutect2, varscan2
- C7orf65 | n.413G>A | RNA (SNP) | VAF 24/131 reads (18%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.351G>A | RNA (SNP) | VAF 12/59 reads (20%) | catalogued as rs776945093; called by muse, mutect2, varscan2
- CR1 | c.487+12353G>A | Intron (SNP) | VAF 23/91 reads (25%) | catalogued as rs770862116, COSV65462406; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792201 C>T | 3'Flank (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23846A>T | Intron (SNP) | VAF 33/55 reads (60%) | catalogued as COSV101045220; called by muse, mutect2, varscan2
- SWI5 | c.-96C>T | 5'UTR (SNP) | VAF 17/45 reads (38%) | catalogued as COSV60791472; called by muse, mutect2, varscan2
